Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7301, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7301-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

Surgical Pathology Report

[REDACTED]

[REDACTED]

Physician(s): [REDACTED]

Phy Locat [REDACTED]

=====

CLINICAL HISTORY

Not Given

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, Left posterior frontal, excision biopsy
B: Brain, enhanced parts of tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A, B C, Brain, left posterior frontal, tumor resection:
Oligodendroglioma, MIB-1 : about 4%

COMMENT

This tumor is an oligodendroglioma with a microcystic loose
background.

Nuclear atypia is mild and mitosis is not found.

There is no vascular hyperplasia nor necrosis.

Electronically Signed Out

[REDACTED]

[REDACTED]

=====

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED]

Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of methylated MGMT promoter is detected.

Results-Comments

Received paraffin sections labeled dated [REDACTED]

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR
amplification of

[page 2 of 3]
both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the AP Molecular Pathology laboratory as required by [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out
[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

Brain, Left posterior frontal, excision biopsy: Glioma, 1 block, [REDACTED]

[REDACTED] Senior Staff Pathologist

GROSS DESCRIPTION

A. Multiple tissue fragments, 0.2 to 0.5 cm, all in A1, A2

B.

SPECIMEN: Enhanced part of tumor.

FIXATIVE: None.

GENERAL: Received are multiple pink-tan, glistening fragments of soft tissue,

2.0 x 1.7 x 0.2 cm in aggregate.

SECTIONS: Entirely submitted in B1.

[REDACTED]

ICD-9(s):

191.9 191.9

Billing Fee Code(s):
[REDACTED]

Histo Data

Part A: Brain, Left posterior frontal, excision biopsy

Taken: [REDACTED]

Received: [REDACTED]

Stain/cnt

Block

Ordered

Comment

H/E x 1

1 [REDACTED]

[page 3 of 3]
x 1	1	
H/E x 1	2	
FS H/E x 1	(none)	

Part B: Brain, enhanced parts of tumor, excision biopsy

Taken:		Received:	
Stain/cnt	Block	Ordered	Comment
mGFAP-DA x 1	1		
H/E x 1	1		
MGMT x 1	1		
MIB1-DA x 1	1		

*** End of Report ***

Source: NCI Genomic Data Commons file dfcad37a-686d-485a-a878-e7d40a85ec2f (TCGA-DU-7301.8FF62D9F-003F-4194-8CC6-BCE45A7CDF1D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).